Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6315, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6315-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. LEFT COLON

SPECIMEN(S):

A. LEFT COLON

GROSS DESCRIPTION:

A. LEFT COLON

Received fresh is an unoriented, closed segment of colon measuring 28 cm in length. The external circumference is 8.2 cm. The serosa has numerous adhesions and a firm nodule measuring 11 x 8.5 x 6 cm. The serosa is inked black. The specimen is opened; there is an annular, indurated, ulcerated mass with serpentine borders measuring 10.7 x 8.5 x 6 cm. It is necrotic and extends through the muscular propria into the mesocolonic fat. It is located 8 and 10 cm from either surgical margin. 2.5 cm from the mass and 7.5 cm from the margin is a pedunculated polyp measuring 4.5 x 3.7 x 3 cm. It has superficial a depth of invasion. Extending from the sessile polyp to the margin are numerous polyps ranging from 0.1 to 0.3 cm. Multiple lymph nodes are identified. A portion of the mass is submitted for tissue procurement. Representative sections are submitted as follows:

A1-A2: margins

A3-A5: mass including deep margin

A6-A7: mesocolonic fat and mass

A8: mass and possible diverticula

A9-A10: mass in relationship to normal-appearing mucosa

A11-A14: mass extending into the mesocolonic fat

A15: polyps

A16-A17: section of pedunculated polyp en bloc

A18: pedunculated polyp and stalk

A19: pedunculated polyp

A20: normal-appearing mucosa

A21-A24: proximal 6 lymph nodes each

A25-A27: proximal 4 lymph nodes each

A28: proximal 1 matted lymph node

A30-A38: distal 6 possible lymph nodes each

A39-A40: distal 2 bisected lymph nodes each

DIAGNOSIS:

A. LEFT COLON, RESECTION:

-MODERATELY DIFFERENTIATED ADENOCARCINOMA OF COLON, INFILTRATING THROUGH MUSCULARIS PROPRIA INTO SUBSEROA WITH PERINEURAL INVASION.

- EXTENSIVE INTRAMURAL SUPPURATIVE NECROSIS

-TUBULOVILLOUS ADENOMA WITH FOCAL HIGH GRADE DYSPLASIA

-HYPERPLASTIC POLYPS(MULTIPLE)

-MARGINS NEGATIVE

-METASTATIC ADENOCARCINOMA IN ONE OF EIGHTY TWO LYMPH NODES (1/82)

-SEE SYNOPTIC REPORT

SYNOPTIC REPORT - COLON & RECTUM

Specimens Involved

Specimens: A: LEFT COLON

Specimen Type: Left hemicolectomy

Tumor Site: Left (descending) colon

Tumor Configuration: Exophytic (polypoid)

Ulcerating

Tumor size: 10.7cm Additional dimensions 8.5cm x 6cm

WHO Classification

Adenocarcinoma 8140/3

Histologic Grade: G2: Moderately differentiated

Extent of Invasion: Subserosa

Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)

Distance of invasive carcinoma from closest margin: 0.1cm

Venous/Lymphatic Invasion: Absent

Perineural Invasion: Present

[page 2 of 2]
[REDACTED]

Additional Pathologic Findings: Adenoma

HYPERPLASTIC POLYPS

Extent of Resection: R0: Complete resection with grossly and microscopically negative margins

Lymph Nodes: Positive 1 / 82

Extranodal extension: Absent

Implants: Absent

Pathological Staging (pTNM): pT 3 N 1 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Colon mass

[REDACTED]

Source: NCI Genomic Data Commons file 21b8d2f9-37f6-4191-9067-e1988dbe866e (TCGA-G4-6315.E940AB4D-6FF9-4BD2-ABCF-FBFA40CA9F39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).